CGCI case HTMCP-03-06-02063 — HIV+ Tumor Molecular Characterization Project - Cervical Cancer (CGCI-HTMCP-CC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a7814814-6a54-425f-a7cd-a58b3e510ea1

Demographics
Sex at birth: female; Race: black or african american; Age at index: 62 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, nonkeratinizing, NOS: ICD-O-3 morphology code: 8072/3; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Year of diagnosis: 2014; Method of diagnosis: Biopsy; AJCC clinical T: T2b; AJCC clinical N: NX; AJCC clinical M: MX; FIGO stage: Stage IIB; FIGO staging edition year: 2009; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 483 days (1.3 years).
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 36 days; Days to treatment end: 59 days; Treatment dose: 45.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Treatment dose: 4500; Treatment anatomic sites: Pelvis.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.

Follow-up (2 entries)
- Days to follow up: 0 days; Disease response: With Tumor; Karnofsky performance status: 80; ECOG performance status: 1.
- Follow-up contacts recording only the day: day 59, day 93, day 483.

Molecular and laboratory tests
- CDKN2A (IHC): Positive.

Other clinical attributes
- Day 0: Weight: 48 kg; Height: 158 cm; BMI: 19.2; Hormonal contraceptive use: Never Used; Hysterectomy type: Not Performed; Menopause status: Postmenopausal; Pregnant at diagnosis: No.
- Day 0: Pregnancy outcome: Miscarriage.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (4 samples)
- Samples HTMCP-03-06-02063-01A, HTMCP-03-06-02063-01B (2 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-03-06-02063-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-03-06-02063-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 6; Pregnancies count miscarriage: 3; Pregnancies count induced abortion: 0; Pregnancies count ectopic: 0; Pregnancies count stillbirth: 0; Total pregnancy count: 9; Tobacco smoking history indicator: 1; Submitted tumor site: Cervical; Histologic diagnosis: Squamous Cell Carcinoma, Non-Keratinizing; Keratinization squamous cell: Non-keratinizing squamous cell carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Hysterectomy Performed Ind-3: No; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease: HIV status: Negative.
- Follow-up form 1, Treatment, Radiation therapy info: Radiation therapy xrt type: External beam radiation.
- Treatments, Treatment: Therapy regimen: Initial; Treatment type: Radiation Therapy; Radiation therapy end: Yes; Radiation therapy total dosage: 45.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-03-06-02063-01A-01R-4427:
- % tumour top: 70
- % tumour bottom: 60

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-03-06-02063-01A-01D-4427:
- % tumour top: 70
- % tumour bottom: 60

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-03-06-02063-10A-01D-4427:
- % tumour top: 0
- % tumour bottom: 0

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-03-06-02063-01B-01S-6335:
- % tumour top: 90

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-03-06-02063-01B-01E-6335:
- % tumour top: 90

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementSpreadsheet03_20191126.xlsx, for sample HTMCP-03-06-02063-01A-02R-4427:
- % tumour top: 70
- % tumour bottom: 60

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementSpreadsheet03_20191126.xlsx, for sample HTMCP-03-06-02063-01A-03R-4427:
- % tumour top: 70
- % tumour bottom: 60
